Somatic mutation profile of tumor specimen PCProject_0399_T2_WES (aliquot PCProject_0399_T2_WES_1) from CMI case PCProject_0399, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 68.5 years (25,021 days).
Specimen PCProject_0399_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2791e099-38d7-4e80-a6d4-2d3faa6b5cc6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0399_SALIVA (DNA), aliquot PCProject_0399_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f07bda77-f66a-45c2-870e-cb762c495982

The open-access MAF lists 49 somatic variants for this specimen: 28 protein-altering or splice-affecting, 8 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Intron 8, Silent 8, Nonsense Mutation 4, Splice Site 2, 3'Flank 1, 3'UTR 1, RNA 1, 5'UTR 1, Splice Region 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.254-2del p.X85_splice | Splice Site (DEL) | VAF 24/104 reads (23%) | hotspot (GDC flag); catalogued as COSV100911416, COSV64300109; called by mutect2, pindel, varscan2
- SPOP | c.397T>G p.F133V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.554); catalogued as rs1057519966, COSV61652724, COSV61652960, COSV61653269; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AKAP9 | c.9994C>T p.R3332* (on ENST00000359028; = p.R3308* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 20/221 reads (9%) | catalogued as rs771217988, COSV62341755; called by muse, mutect2
- CHD8 | c.6130C>T p.R2044* (on ENST00000646647 / NM_001170629.2; = p.R1765* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 10/89 reads (11%) | catalogued as rs772226664, COSV63036406; called by mutect2, varscan2
- CSMD3 | c.2154C>T p.I718= (on ENST00000297405 / NM_001363185.1; = p.I614= on NM_052900.3) | Splice Region (SNP) | VAF 4/28 reads (14%) | catalogued as COSV52202139; called by muse, varscan2
- E2F4 | c.1051G>T p.E351* | Nonsense Mutation (SNP) | VAF 42/164 reads (26%) | catalogued as COSV62607123; called by muse, mutect2, varscan2
- GAS2L3 | c.1433A>G p.H478R | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs757095936; called by muse, mutect2, varscan2
- GRM5 | c.3059C>T p.S1020L (on ENST00000305447 / NM_001143831.2; = p.S988L on NM_000842.4) | Missense Mutation (SNP) | VAF 42/823 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.921); catalogued as rs1309769740; called by muse, mutect2
- HVCN1 | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 46/197 reads (23%) | catalogued as COSV54372189; called by muse, mutect2, varscan2
- IGSF8 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs190351074, COSV58758030, COSV58758532; called by muse, mutect2
- OPN1LW | c.619G>A p.V207M | Missense Mutation (SNP) | VAF 40/314 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs1557157806, COSV64049370; called by muse, mutect2, varscan2
- PRSS23 | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 26/211 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs376501823; called by muse, mutect2
- ABCG1 | c.479G>T p.C160F | Missense Mutation (SNP) | VAF 106/569 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- C5AR2 | c.211A>C p.T71P | Missense Mutation (SNP) | VAF 22/676 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.544); called by muse, mutect2
- CCDC168 | c.20373G>T p.E6791D | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.028); called by mutect2, varscan2
- CEBPD | c.563A>G p.D188G | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.123); called by muse, mutect2
- DMRTA2 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.199); called by muse, mutect2
- ETV3 | c.47-12_47del p.X16_splice | Splice Site (DEL) | VAF 20/98 reads (20%) | called by pindel, varscan2
- FOXK1 | c.969C>A p.D323E | Missense Mutation (SNP) | VAF 42/886 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.734); called by muse, mutect2
- GABBR1 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 164/799 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAST2 | c.5272C>T p.P1758S | Missense Mutation (SNP) | VAF 32/410 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); called by muse, mutect2
- NR3C2 | c.451C>A p.P151T | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2
- PADI3 | c.764C>G p.S255C | Missense Mutation (SNP) | VAF 30/246 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PYCARD | c.103G>A p.G35S | Missense Mutation (SNP) | VAF 44/768 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RABEP1 | c.1947T>G p.N649K | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, varscan2
- SIX1 | c.281_293del p.E94Gfs*154 | Frame Shift Del (DEL) | VAF 55/357 reads (15%) | called by mutect2, pindel, varscan2
- TMEM131 | c.2636A>G p.D879G | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMEM135 | c.107A>T p.E36V | Missense Mutation (SNP) | VAF 67/355 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- CNTN2 | c.786C>T p.F262= | Silent (SNP) | VAF 67/313 reads (21%) | catalogued as rs369368742; called by muse, mutect2, varscan2
- DNAH17 | c.10941G>A p.A3647= | Silent (SNP) | VAF 50/380 reads (13%) | catalogued as rs35068504; called by muse, mutect2, varscan2
- DOP1B | c.747C>T p.I249= | Silent (SNP) | VAF 29/140 reads (21%) | catalogued as rs1381166033, COSV67693073; called by muse, mutect2, varscan2
- KDM4B | c.2613C>T p.Y871= | Silent (SNP) | VAF 21/200 reads (11%) | catalogued as rs377371964; called by muse, mutect2, varscan2
- NWD2 | c.3100T>C p.L1034= | Silent (SNP) | VAF 15/104 reads (14%) | called by muse, mutect2, varscan2
- PRPF8 | c.6312C>T p.Y2104= | Silent (SNP) | VAF 40/229 reads (17%) | called by muse, mutect2, varscan2
- PRPH2 | c.501C>A p.G167= | Silent (SNP) | VAF 24/312 reads (8%) | called by muse, mutect2
- TTF1 | c.2685T>C p.S895= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as rs1334807300, COSV57502936; called by muse, mutect2
- BSG | c.416-38C>T | Intron (SNP) | VAF 21/228 reads (9%) | catalogued as rs749006346; called by muse, mutect2
- C5 | c.2563-2231G>C | Intron (SNP) | VAF 6/48 reads (13%) | catalogued as rs1309194751; called by mutect2, varscan2
- CCNL2 | c.1007-598A>G | Intron (SNP) | VAF 6/53 reads (11%) | catalogued as rs1210914950; called by mutect2, varscan2
- CFL2 | chr14:34714632 G>A | 5'Flank (SNP) | VAF 66/265 reads (25%) | catalogued as rs1179746459; called by muse, mutect2, varscan2
- DYNC1LI1 | c.220+3717C>A | Intron (SNP) | VAF 8/83 reads (10%) | catalogued as rs974796946; called by muse, mutect2
- FAM161A | c.*618A>G | 3'UTR (SNP) | VAF 5/41 reads (12%) | catalogued as rs980814053; called by muse, varscan2
- MAP3K15 | c.1749-1263A>C | Intron (SNP) | VAF 8/94 reads (9%) | catalogued as rs1307001562; called by muse, mutect2
- NCF1C | n.1231del | RNA (DEL) | VAF 22/158 reads (14%) | called by mutect2, varscan2
- NUDT18 | c.-86_-85insAGAGCGGTCTCCGCAGGGACTG | 5'UTR (INS) | VAF 3/44 reads (7%) | called by mutect2, pindel
- PADI4 | c.340+485A>G | Intron (SNP) | VAF 10/104 reads (10%) | catalogued as rs1036598090; called by muse, mutect2
- PDIA3P1 | chr1:147179324 C>G | 3'Flank (SNP) | VAF 37/240 reads (15%) | called by muse, mutect2, varscan2
- TYK2 | c.194-1368T>C | Intron (SNP) | VAF 6/103 reads (6%) | catalogued as rs1386730107; called by muse, mutect2
- YIPF3 | c.395+329G>T | Intron (SNP) | VAF 30/347 reads (9%) | catalogued as rs1383044718, COSV104411955; called by muse, mutect2
